Somatic mutation profile of tumor specimen MMRF_1424_2_BM_CD138pos (aliquot MMRF_1424_2_BM_CD138pos_T1_KBS5U_L06436) from MMRF case MMRF_1424, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 40.5 years (14,797 days).
Specimen MMRF_1424_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a29a1d5-bd25-4731-99ce-11fdf677f59b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1424_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1424_1_PB_Whole_C2_KAS5U_L01606; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd289265-dcc3-4cc5-99a5-7f04dc2ee7c0

The open-access MAF lists 2 somatic variants for this specimen: 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDOST | c.*503T>C | 3'UTR (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- PPP3R1 | chr2:68252997 G>A | 5'Flank (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
